HCMI case HCM-BROD-0098-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9097285b-eeb1-4f36-a0ab-0d0592043792

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1940; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.2; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 77.3 years (28,226 days); AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; Metastasis at diagnosis: No Metastasis; Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported); Surgery, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 31 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 31 days.
- Days to follow up: 58 days; Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 43.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol intensity: Non-Drinker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples)
- Sample HCM-BROD-0098-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample HCM-BROD-0098-C15-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0098-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
